Somatic mutation profile of tumor specimen MP2PRT-PASJVH-TBP1-A (aliquot MP2PRT-PASJVH-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASJVH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,799 days).
Specimen MP2PRT-PASJVH-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76a88c23-756c-4c67-92af-011e4b62d3bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJVH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJVH-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c455ae9-fc07-4584-b995-8c635f35faca

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 6, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDYL2 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 125/314 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs1350858763, COSV73653861; called by muse, mutect2, varscan2
- DMKN | c.897C>A p.D299E | Missense Mutation (SNP) | VAF 18/699 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.029); catalogued as COSV100303333; called by muse, mutect2
- FBXO31 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 266/590 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs764983253, COSV61148172; called by muse, varscan2
- GPC2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 214/480 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs772546554, COSV104392342; called by muse, mutect2, varscan2
- TRIP10 | c.1205G>A p.R402Q (on ENST00000313244 / NM_001288962.2; = p.R346Q on NM_004240.4) | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs756396774, COSV57569548; called by muse, mutect2, varscan2
- CREBBP | c.5936_5937insAGGACAA p.N1979Kfs*364 | Frame Shift Ins (INS) | VAF 221/612 reads (36%) | called by mutect2, pindel, varscan2
- ENO4 | c.638-1G>A p.X213_splice (on ENST00000622726; = p.X212_splice on NM_001242699.2) | Splice Site (SNP) | VAF 83/219 reads (38%) | called by muse, mutect2, varscan2
- KRT1 | c.295T>A p.F99I | Missense Mutation (SNP) | VAF 103/769 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CDH7 | c.531G>A p.A177= | Silent (SNP) | VAF 131/298 reads (44%) | catalogued as rs567500655, COSV59881966; called by muse, mutect2, varscan2
- KCND2 | c.93G>A p.P31= | Silent (SNP) | VAF 240/539 reads (45%) | catalogued as COSV100475093; called by muse, mutect2, varscan2
- LAMA2 | c.6789G>A p.T2263= | Silent (SNP) | VAF 80/593 reads (13%) | catalogued as rs770541414; called by muse, mutect2, varscan2
- PDILT | c.612A>G p.G204= | Silent (SNP) | VAF 138/322 reads (43%) | called by muse, mutect2, varscan2
- PPP4R3C | c.744C>T p.F248= | Silent (SNP) | VAF 137/468 reads (29%) | catalogued as rs1296792012; called by muse, mutect2, varscan2
- TKTL2 | c.843G>A p.Q281= | Silent (SNP) | VAF 141/544 reads (26%) | catalogued as COSV54920812; called by muse, mutect2, varscan2
- ZBTB33 | c.546G>A p.K182= | Silent (SNP) | VAF 128/545 reads (23%) | catalogued as COSV100434158; called by muse, varscan2
